Gene-level copy-number profile of tumor specimen TCGA-IB-7887-01A from TCGA case TCGA-IB-7887, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 62.9 years (22,990 days).
Specimen TCGA-IB-7887-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.716d013a-6800-4bf1-91ef-766da8ec6c22.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-7887-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f29ac876-4ed9-4666-857d-07363dade916

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 128; copy number 2: 13,295; copy number 3: 56; copy number 4: 43,893; copy number 5: 22; copy number 6: 2,196; copy number 8: 181; copy number 10: 2; copy number 13: 22; copy number 15: 8; copy number 17: 11; copy number 20: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IB-7887-01A-11D-2153-01): tumor purity 0.34, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 128 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,386,927–26,644,595, 102 genes (broad region; genes not listed).
- chr18:50,560,087–53,535,903, 26 genes (within-gene range 0–2): MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1, DCC, AC011155.1, VN1R76P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 44 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:85,799,987–85,828,050, 1 gene, copy number 20: CADM2-AS2.
- chr6:18,522,735–18,674,001, 2 genes, copy number 10 (within-gene range 2–10): MIR548A1HG, MIR548A1.
- chr6:72,522,641–72,622,073, 3 genes, copy number 13: FO393414.2, FO393414.1, FO393414.3.
- chr17:52,390,515–56,595,611, 38 genes, copy number 13–17: LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1, AC006600.2, RPL39P33, NOG.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
